Somatic mutation profile of tumor specimen TCGA-DU-8162-01A (aliquot TCGA-DU-8162-01A-21D-2253-08) from TCGA case TCGA-DU-8162, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 61.9 years (22,596 days).
Specimen TCGA-DU-8162-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06f9f396-58c0-44b2-9080-9687707d9262.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-8162-10A (Blood Derived Normal), aliquot TCGA-DU-8162-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1731b310-c06d-44ff-b974-b82f6182ba61

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 13, Silent 9, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 199/352 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP4A | c.2222T>A p.I741N | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52869907; called by muse, mutect2, varscan2
- C4BPA | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65536145, COSV65536939; called by muse, mutect2, varscan2
- FLNC | c.5500C>T p.H1834Y | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs377141822; ClinVar: uncertain significance; called by muse, mutect2
- FOXQ1 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780504140, COSV57259181; called by muse, mutect2, varscan2
- IGKV3-20 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs548180684; called by muse, mutect2, varscan2
- MYOM2 | c.1463-1G>A p.X488_splice | Splice Site (SNP) | VAF 49/408 reads (12%) | catalogued as COSV50738204; called by muse, mutect2, varscan2
- NUTM1 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.388); catalogued as rs1176636592, COSV61547878; called by muse, mutect2
- RFX4 | c.671T>G p.V224G (on ENST00000392842 / NM_213594.3; = p.V130G on NM_032491.6) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57578262; called by muse, mutect2, varscan2
- RRAS | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1287689249, COSV55868832; called by muse, mutect2, varscan2
- RSKR | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV56382987; called by muse, mutect2, varscan2
- SLC1A6 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1430616951, COSV55667690; called by muse, mutect2, varscan2
- TAS2R1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs145804099, COSV101225699; called by muse, mutect2, varscan2
- SETD2 | c.4221del p.R1408Gfs*4 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- XKR3 | c.1310T>C p.L437P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CYP4F12 | c.459C>T p.P153= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs199991130, COSV100215575; called by muse, mutect2, varscan2
- FBXO24 | c.264G>A p.P88= (on ENST00000241071 / NM_033506.3; = p.P126= on NM_012172.5) | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs775707941, COSV53827945; called by muse, mutect2, varscan2
- HMCN1 | c.8892A>T p.P2964= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV54919773; called by muse, mutect2
- IQSEC3 | c.2844C>T p.L948= (on ENST00000538872 / NM_001170738.2; = p.L645= on NM_015232.1) | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as rs782297475, COSV58287734; called by muse, mutect2
- NYNRIN | c.3615G>A p.G1205= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV66843744; called by muse, mutect2, varscan2
- OPN4 | c.495C>T p.A165= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs1478669903, COSV54117700; called by muse, mutect2, varscan2
- PIGG | c.2718G>A p.L906= (on ENST00000453061 / NM_001127178.3; = p.L898= on NM_017733.4) | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV56319787; called by muse, mutect2
- SEPTIN6 | c.759G>A p.A253= | Silent (SNP) | VAF 21/184 reads (11%) | catalogued as rs143382025, COSV59715805; called by muse, mutect2, varscan2
- SLC22A16 | c.138C>T p.V46= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV57931939; called by muse, mutect2, varscan2
